Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6463, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6463-01A (Primary Tumor).

		LARGE INTESTINE TISSUE CHECKLIST Specimen type: Colectomy Specimen size: Not specified Tumor site: Transverse colon Tumor size: 2.5 x 4 x 3 cm Tumor features: None specified Histologic type: Mucinous adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Pericolonic tissues Lymph nodes: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
--	--	---

--

Source: NCI Genomic Data Commons file e02421e9-2738-4a49-9a07-4b85b785e69e (TCGA-F4-6463.A06E1C69-5737-4692-950C-4EF74CED2D03.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).